Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3710, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3710-01A (Primary Tumor).

Diagnosis:

This is a poorly differentiated adenocarcinoma of the colon (right colon flexure) of histopathological differentiation grade G3, with ulceration and erosions of the inner surface of the tumor, peritumorous, chronic recurrent concomitant inflammation, accompanied by an acute inflammatory flare, with carcinomatous lymphangitis, tumor infiltration in the parietal layers of the colon as far as the extramucosal, subserous fatty connective tissue, with tumor-free lymph nodes (0/20), moderate chronic lymphadenitis, with a diverticulum in the tumor. Tumor-free overview slices from all other resection margins identified, from the perivascular fatty tissue of the central ligature and the omental fatty tissue.

According to the sections available, the tumor spread the colon carcinoma corresponds to a tumor stage of pT3, pN0, MX, L1, R0.

Tumor classification:

ICDO-DA-M 8140/3

Source: NCI Genomic Data Commons file e1acab91-092d-44f2-8d33-919c1ec8906c (TCGA-AA-3710.CAFE6B42-0750-48E0-80FE-3AACAA8FC9B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).